Somatic mutation profile of tumor specimen MMRF_2609_1_BM_CD138pos (aliquot MMRF_2609_1_BM_CD138pos_T1_KHS5U_L13294) from MMRF case MMRF_2609, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.2 years (23,814 days).
Specimen MMRF_2609_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c6eeabf-f8ce-45b6-9e64-d244be76b1b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2609_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2609_1_PB_WBC_C2_KHS5U_L13295; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01b4a33e-aa93-4f75-9f7f-0d3b81519dff

The open-access MAF lists 68 somatic variants for this specimen: 25 protein-altering or splice-affecting, 7 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 23, Missense Mutation 21, Intron 9, Silent 7, RNA 2, Splice Region 2, 5'Flank 2, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD30B | c.502C>A p.Q168K | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62810534; called by muse, mutect2
- CFDP1 | c.444G>C p.L148F | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs895709541; called by muse, mutect2, varscan2
- CHST6 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.02); catalogued as rs1485683554, COSV59999622; called by muse, mutect2, varscan2
- EIF5 | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 80/225 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as rs993369094, COSV104370577, COSV99384640; called by muse, mutect2, varscan2
- EPHA3 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 129/291 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as COSV100346265, COSV60704539; called by muse, mutect2, varscan2
- FGFR2 | c.1361C>T p.T454M | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs148672240; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- H2BC9 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 69/178 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.415); catalogued as rs1454321085; called by muse, mutect2, varscan2
- IGKJ4 | c.23del p.K8Rfs*? | Frame Shift Del (DEL) | VAF 15/90 reads (17%) | catalogued as rs761375752; called by muse*, pindel
- IGLL5 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1328966886; called by muse, mutect2, varscan2
- IPO8 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 92/200 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.094); catalogued as rs754996257, COSV99805491; called by muse, mutect2, varscan2
- KMT2A | c.5530C>T p.P1844S | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.088); catalogued as rs551537456, COSV63294105; called by muse, mutect2, varscan2
- SP140 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as COSV100613602; called by muse, mutect2, varscan2
- SULT1C3 | c.490T>G p.L164V | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as rs1217929698, COSV61252245; called by muse, mutect2, varscan2
- TANC2 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV67343879; called by muse, mutect2, varscan2
- ASXL3 | c.4964T>C p.L1655P | Missense Mutation (SNP) | VAF 83/199 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- COLGALT1 | c.67C>A p.L23M | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.133); called by muse, mutect2
- GIMAP2 | c.425T>G p.I142S | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGKV1-5 | c.8T>C p.M3T | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT deleterious (0.05); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- KATNAL2 | c.1098T>G p.S366= (on ENST00000356157 / NM_001353899.1; = p.S294= on NM_031303.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 43/98 reads (44%) | called by muse, mutect2, varscan2
- LAMB2 | c.461C>T p.T154I | Missense Mutation (SNP) | VAF 50/91 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MED17 | c.1467-4A>G | Splice Region (SNP) | VAF 56/198 reads (28%) | called by muse, mutect2, varscan2
- NEDD1 | c.1366G>A p.V456I | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- PNN | c.569A>G p.N190S | Missense Mutation (SNP) | VAF 183/418 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- PTPRO | c.1118A>G p.E373G | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- TSR1 | c.94_95insC p.K32Tfs*75 | Frame Shift Ins (INS) | VAF 26/70 reads (37%) | called by mutect2, pindel, varscan2
- FGF5 | c.405A>G p.G135= | Silent (SNP) | VAF 87/133 reads (65%) | called by muse, mutect2, varscan2
- HHIPL1 | c.306G>A p.T102= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs375473578; called by muse, mutect2, varscan2
- KIAA1671 | c.2256G>A p.P752= | Silent (SNP) | VAF 43/106 reads (41%) | catalogued as rs1287816835; called by muse, mutect2, varscan2
- OR7A5 | c.360T>C p.Y120= | Silent (SNP) | VAF 252/418 reads (60%) | called by muse, mutect2, varscan2
- PFN1 | c.387T>C p.Y129= | Silent (SNP) | VAF 84/204 reads (41%) | catalogued as rs762351868; called by muse, mutect2, varscan2
- RYR1 | c.12450G>A p.S4150= | Silent (SNP) | VAF 108/396 reads (27%) | called by muse, mutect2, varscan2
- ZNF135 | c.1206G>A p.R402= (on ENST00000313434 / NM_001289401.2; = p.R414= on NM_003436.4) | Silent (SNP) | VAF 37/370 reads (10%) | called by muse, mutect2, varscan2
- CACNA1I | c.*2504C>A | 3'UTR (SNP) | VAF 92/189 reads (49%) | called by muse, mutect2, varscan2
- CC2D2A | c.*55A>C | 3'UTR (SNP) | VAF 35/117 reads (30%) | called by muse, mutect2, varscan2
- DNAJB13 | c.607-218C>G | Intron (SNP) | VAF 12/48 reads (25%) | catalogued as rs559297688; called by mutect2, varscan2
- DOK4 | c.*246T>C | 3'UTR (SNP) | VAF 34/82 reads (41%) | catalogued as rs1361832294; called by muse, mutect2, varscan2
- EBF3 | c.913-36G>A | Intron (SNP) | VAF 45/112 reads (40%) | catalogued as rs377405475, COSV62479279; called by muse, mutect2, varscan2
- EHD1 | c.*2454del | 3'UTR (DEL) | VAF 29/224 reads (13%) | called by mutect2, pindel, varscan2
- ELL2 | c.*1707A>G | 3'UTR (SNP) | VAF 36/65 reads (55%) | catalogued as rs866426269; called by muse, mutect2, varscan2
- GNPNAT1 | c.*2357C>T | 3'UTR (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2
- HGF | c.*1686C>A | 3'UTR (SNP) | VAF 46/93 reads (49%) | called by muse, mutect2, varscan2
- ITM2C | c.*237T>G | 3'UTR (SNP) | VAF 57/141 reads (40%) | called by muse, mutect2, varscan2
- KCNMA1 | c.*989T>C | 3'UTR (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2, varscan2
- KNOP1P1 | n.122G>A | RNA (SNP) | VAF 75/185 reads (41%) | called by muse, mutect2, varscan2
- LAT | chr16:28984905 ins G | 5'Flank (INS) | VAF 28/82 reads (34%) | catalogued as rs749637413; called by mutect2, varscan2
- MALAT1 | n.56T>A | RNA (SNP) | VAF 53/148 reads (36%) | called by muse, mutect2, varscan2
- MCAM | c.*140T>C | 3'UTR (SNP) | VAF 27/80 reads (34%) | called by muse, mutect2, varscan2
- MOV10 | c.1982-14C>T | Intron (SNP) | VAF 72/101 reads (71%) | catalogued as rs772765284; called by muse, mutect2, varscan2
- MUCL3 | c.947-426C>T | Intron (SNP) | VAF 12/310 reads (4%) | catalogued as rs1456464241, COSV58517017; called by muse, mutect2
- OSBPL6 | c.*1968A>G | 3'UTR (SNP) | VAF 28/65 reads (43%) | called by muse, mutect2, varscan2
- PCDH10 | c.*496A>C | 3'UTR (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- PITX3 | c.*235G>A | 3'UTR (SNP) | VAF 40/91 reads (44%) | called by muse, mutect2, varscan2
- PPFIA2 | c.1267-39A>G | Intron (SNP) | VAF 18/282 reads (6%) | called by muse, mutect2
- PSEN1 | c.*2581G>A | 3'UTR (SNP) | VAF 48/108 reads (44%) | catalogued as rs942950807; called by muse, mutect2, varscan2
- PTBP2 | c.*1130G>A | 3'UTR (SNP) | VAF 24/63 reads (38%) | called by muse, mutect2, varscan2
- RAB36 | c.*141C>A | 3'UTR (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- RAD50 | c.1793+1268G>T | Intron (SNP) | VAF 34/186 reads (18%) | called by muse, mutect2, varscan2
- REG1A | c.321+63T>G | Intron (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2, varscan2
- SARM1 | c.*6154T>C | 3'UTR (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- SCAPER | c.772+2025A>G | Intron (SNP) | VAF 62/102 reads (61%) | catalogued as COSV57735875; called by muse, mutect2, varscan2
- SLC2A4RG | c.*671G>A | 3'UTR (SNP) | VAF 39/94 reads (41%) | called by muse, mutect2, varscan2
- SLC35E3 | c.*2412A>G | 3'UTR (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2
- SPEF2 | c.2839+806G>A | Intron (SNP) | VAF 29/125 reads (23%) | called by muse, mutect2, varscan2
- STPG2 | c.*2770T>A | 3'UTR (SNP) | VAF 41/157 reads (26%) | called by muse, mutect2, varscan2
- TMEM241 | c.*1301A>T | 3'UTR (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- TMEM241 | c.*1251A>G | 3'UTR (SNP) | VAF 10/33 reads (30%) | called by muse, varscan2
- TMSB4X | chrX:12975584 G>A | 5'Flank (SNP) | VAF 93/113 reads (82%) | catalogued as rs781125291; called by muse, mutect2, varscan2
- TTC26 | c.*2161del | 3'UTR (DEL) | VAF 34/87 reads (39%) | catalogued as rs1050223194; called by mutect2, varscan2
